Somatic mutation profile of tumor specimen ALCH-B20Z-TTP1-A (aliquot ALCH-B20Z-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B20Z, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.8 years (27,685 days).
Specimen ALCH-B20Z-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7707cae9-4871-4f32-a34e-09665bad2fd6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B20Z-NB1-A (Blood Derived Normal), aliquot ALCH-B20Z-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45971c5d-37d2-4506-9954-d4e365d63bbe

The open-access MAF lists 32 somatic variants for this specimen: 24 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 6, Nonsense Mutation 2, Intron 1, Frame Shift Ins 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC068580.4 | c.268dup p.Q90Pfs*50 | Frame Shift Ins (INS) | VAF 24/170 reads (14%) | catalogued as rs752612332; ClinVar: pathogenic; called by mutect2, varscan2
- MTOR | c.7498A>T p.I2500F | Missense Mutation (SNP) | VAF 14/418 reads (3%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1057519916, COSV63869574; ClinVar: likely pathogenic; called by muse, mutect2
- ABCG2 | c.410G>C p.R137T | Missense Mutation (SNP) | VAF 30/468 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs748501399, COSV52949598; called by muse, mutect2
- CPEB2 | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated, low confidence (0.08); catalogued as rs984648134; called by muse, mutect2, varscan2
- DAO | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 46/499 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs749872143, COSV57322593; called by muse, mutect2
- KLHL2 | c.587A>G p.N196S | Missense Mutation (SNP) | VAF 37/291 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs768758846, COSV56974875; called by muse, mutect2, varscan2
- MASP2 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 30/544 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs775120367, COSV68896171; called by muse, mutect2
- MYH7 | c.4353+1G>A p.X1451_splice | Splice Site (SNP) | VAF 35/215 reads (16%) | catalogued as rs964377649; called by muse, mutect2, varscan2
- MYO7A | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781790246; called by muse, mutect2
- NPAP1 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.038); catalogued as COSV61510326; called by muse, mutect2, varscan2
- PTEN | c.196A>G p.K66E | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64293954, COSV64310841; called by muse, mutect2, varscan2
- SETD2 | c.5392G>T p.E1798* | Nonsense Mutation (SNP) | VAF 45/274 reads (16%) | catalogued as COSV57436776; called by muse, mutect2, varscan2
- ZNF74 | c.782C>G p.S261C | Missense Mutation (SNP) | VAF 41/282 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV62623049; called by muse, mutect2, varscan2
- ABCA10 | c.1987T>A p.L663M | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- APBB3 | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 40/450 reads (9%) | called by muse, mutect2
- C12orf66 | c.1098G>T p.M366I | Missense Mutation (SNP) | VAF 49/328 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- CDC40 | c.1369G>T p.A457S | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); called by muse, mutect2
- COL8A1 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 7/199 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, mutect2
- CYLD | c.1655C>T p.S552F | Missense Mutation (SNP) | VAF 94/681 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- FDXR | c.923T>G p.F308C (on ENST00000293195 / NM_024417.5; = p.F314C on NM_004110.6) | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IGSF22 | c.136A>G p.S46G | Missense Mutation (SNP) | VAF 37/325 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PCDH11X | c.109A>G p.N37D | Missense Mutation (SNP) | VAF 122/467 reads (26%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAP1 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 65/413 reads (16%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TCTEX1D1 | c.311G>A p.R104K | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DHX32 | c.261T>A p.A87= | Silent (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2, varscan2
- H3C1 | c.261C>T p.S87= | Silent (SNP) | VAF 46/591 reads (8%) | catalogued as rs769071970; called by muse, mutect2
- IRX3 | c.1440C>G p.P480= | Silent (SNP) | VAF 45/338 reads (13%) | catalogued as COSV100315258; called by muse, mutect2, varscan2
- RBM25 | c.1383T>G p.L461= | Silent (SNP) | VAF 32/199 reads (16%) | called by muse, varscan2
- SCAF4 | c.435A>T p.A145= | Silent (SNP) | VAF 28/1084 reads (3%) | called by muse, mutect2
- SLC7A3 | c.1110C>T p.F370= | Silent (SNP) | VAF 94/290 reads (32%) | called by muse, mutect2, varscan2
- HERC2P3 | n.175T>G | RNA (SNP) | VAF 94/909 reads (10%) | called by muse, mutect2, varscan2
- SNRNP200 | c.4164+13G>A | Intron (SNP) | VAF 31/278 reads (11%) | catalogued as rs373668832; called by muse, mutect2, varscan2
